CCDI case PBBTYI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9baf4630-cbaf-495a-8742-683e8270fdca

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (317 days).

Biospecimens (3 samples)
- Sample 0DHPJ7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHPJH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHPKE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
